Gene-level copy-number profile of tumor specimen TCGA-EE-A17Z-06A from TCGA case TCGA-EE-A17Z, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 57.6 years (21,041 days).
Specimen TCGA-EE-A17Z-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.578641c8-214e-4ef7-88ae-ffe7d62609b6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A17Z-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e39ef58b-4ade-4b75-b64c-3091f0790291

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 9,340; copy number 2: 43,827; copy number 3: 6,420; copy number 4: 201.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A17Z-06A-11D-A194-01): tumor purity 0.99, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:9,102,630–9,334,445, 9 genes: NDUFV2, AP005263.1, AP005899.1, NDUFV2-AS1, ANKRD12, Y_RNA, Y_RNA, AP001033.2, AP001033.1.
- chr18:9,335,269–9,336,242, 1 gene: AP001033.3.
- chr19:41,998,321–42,378,769, 18 genes (within-gene range 0–1): GRIK5, ZNF574, POU2F2, AC010247.1, MIR4323, AC010247.2, DEDD2, AC006486.3, ZNF526, GSK3A, AC006486.1, AC006486.2, ERF, CIC, PAFAH1B3, PRR19, TMEM145, MEGF8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 6,960. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
